Somatic mutation profile of tumor specimen TCGA-AN-A0AR-01A (aliquot TCGA-AN-A0AR-01A-11W-A019-09) from TCGA case TCGA-AN-A0AR, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 55.2 years (20,152 days).
Specimen TCGA-AN-A0AR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e1db60ce-d476-4d4f-a2fd-7ad0bad7cae6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AN-A0AR-10A (Blood Derived Normal), aliquot TCGA-AN-A0AR-10A-01W-A021-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5a99de4f-7551-4276-a764-3315f1566100

The open-access MAF lists 123 somatic variants for this specimen: 98 protein-altering or splice-affecting, 24 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 78, Silent 24, Frame Shift Del 8, Splice Site 5, Nonsense Mutation 3, In Frame Del 3, Translation Start Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC1 | c.1390C>G p.P464A | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.4); catalogued as COSV60682674; called by muse, mutect2, varscan2
- ABCC9 | c.2066C>G p.S689C | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV53966033; called by muse, mutect2, varscan2
- ACADVL | c.1366C>T p.R456C | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs794727111, COSV50035059; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADGRV1 | c.3804C>A p.N1268K | Missense Mutation (SNP) | VAF 62/78 reads (79%) | SIFT tolerated (0.19); PolyPhen benign (0.08); catalogued as COSV67981492; called by muse, mutect2, varscan2
- ADK | c.88G>T p.G30* (on ENST00000286621; = p.G13* on NM_001123.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 65/78 reads (83%) | catalogued as COSV54202032; called by muse, mutect2, varscan2
- B4GALNT3 | c.1205A>T p.D402V | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as COSV56751105; called by muse, mutect2, varscan2
- BMP4 | c.404A>T p.N135I | Missense Mutation (SNP) | VAF 51/106 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.1); catalogued as COSV55415470; called by muse, mutect2, varscan2
- BMPER | c.952A>C p.N318H | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV51814389, COSV51817398; called by muse, mutect2, varscan2
- C1GALT1 | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 94/210 reads (45%) | SIFT tolerated (0.39); PolyPhen benign (0.052); catalogued as COSV56179004; called by muse, mutect2, varscan2
- CCAR1 | c.2391G>C p.E797D | Missense Mutation (SNP) | VAF 154/340 reads (45%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV56268438; called by muse, mutect2, varscan2
- CD163L1 | c.1328C>A p.S443* | Nonsense Mutation (SNP) | VAF 152/763 reads (20%) | catalogued as COSV100550798, COSV58013325; called by muse, mutect2, varscan2
- CDK5RAP2 | c.1201A>C p.I401L | Missense Mutation (SNP) | VAF 119/273 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV62573144; called by muse, mutect2, varscan2
- CPEB3 | c.1096G>C p.G366R | Missense Mutation (SNP) | VAF 185/282 reads (66%) | SIFT deleterious (0.02); PolyPhen benign (0.261); catalogued as COSV56454853, COSV99800126; called by muse, mutect2, varscan2
- CPN2 | c.593T>A p.L198Q | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV60469929, COSV60470063; called by muse, mutect2, varscan2
- CRTAM | c.104C>T p.T35I | Missense Mutation (SNP) | VAF 14/244 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.092); catalogued as COSV99911927; called by muse, mutect2
- DENND1A | c.720-1G>C p.X240_splice | Splice Site (SNP) | VAF 44/104 reads (42%) | catalogued as COSV65323888; called by muse, mutect2, varscan2
- DYNC2H1 | c.2580G>T p.W860C | Missense Mutation (SNP) | VAF 268/464 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs765676542, COSV62089946; called by muse, mutect2, varscan2
- ENTPD7 | c.772G>T p.D258Y | Missense Mutation (SNP) | VAF 94/170 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65112117; called by muse, mutect2, varscan2
- EPB41L3 | c.2258A>G p.N753S | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.021); catalogued as COSV59448112; called by muse, mutect2, varscan2
- FASTKD1 | c.2168C>G p.T723R | Missense Mutation (SNP) | VAF 117/274 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV71624169; called by muse, mutect2, varscan2
- FASTKD3 | c.341A>T p.E114V | Missense Mutation (SNP) | VAF 51/100 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV52942487; called by muse, mutect2, varscan2
- FCN2 | c.212G>C p.R71T | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.057); catalogued as COSV52476397; called by muse, mutect2, varscan2
- FKBP15 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.182); catalogued as COSV53033121; called by mutect2, varscan2
- FUBP1 | c.1902G>A p.M634I | Missense Mutation (SNP) | VAF 99/120 reads (83%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs1402662465, COSV53928225; called by muse, mutect2, varscan2
- FUT3 | c.710C>T p.T237M | Missense Mutation (SNP) | VAF 54/82 reads (66%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.865); catalogued as rs377154201; called by muse, mutect2, varscan2
- GAD2 | c.1672C>T p.R558C | Missense Mutation (SNP) | VAF 42/895 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200401161, COSV52161150, COSV99394110; called by muse, mutect2
- GALNT17 | c.1576T>G p.C526G | Missense Mutation (SNP) | VAF 50/116 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61153971; called by muse, mutect2, varscan2
- GDF3 | c.821G>A p.R274Q | Missense Mutation (SNP) | VAF 125/362 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.028); catalogued as rs1312136124, COSV61712054; called by muse, mutect2, varscan2
- GRM5 | c.464C>T p.A155V | Missense Mutation (SNP) | VAF 47/195 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59597230; called by muse, mutect2, varscan2
- GZMA | c.49T>C p.S17P | Missense Mutation (SNP) | VAF 79/196 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV57112329; called by muse, mutect2, varscan2
- HEPHL1 | c.3031A>G p.S1011G | Missense Mutation (SNP) | VAF 278/490 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as rs761601480, COSV59890064, COSV59890480; called by muse, mutect2, varscan2
- HROB | c.349G>C p.V117L | Missense Mutation (SNP) | VAF 106/146 reads (73%) | SIFT deleterious (0.05); PolyPhen benign (0.146); catalogued as COSV55369136; called by muse, mutect2, varscan2
- IGSF8 | c.1247G>A p.G416E | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV58757701; called by muse, mutect2, varscan2
- IL17RB | c.829C>T p.P277S | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs1423878942, COSV55472466; called by muse, mutect2, varscan2
- ITGAV | c.2821-1G>T p.X941_splice | Splice Site (SNP) | VAF 56/180 reads (31%) | catalogued as COSV53710584, COSV53712118, COSV99655397; called by muse, mutect2, varscan2
- KALRN | c.6811G>T p.A2271S (on ENST00000360013 / NM_001024660.4; = p.A574S on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT tolerated (0.83); PolyPhen benign (0.018); catalogued as COSV52261663, COSV99361682; called by muse, mutect2
- KCNS2 | c.1255C>T p.R419C | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.586); catalogued as rs781697576, COSV54637693; called by muse, mutect2, varscan2
- KCNU1 | c.2354A>T p.D785V | Missense Mutation (SNP) | VAF 65/174 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67754328; called by muse, mutect2, varscan2
- KDM5A | c.349C>A p.L117M | Missense Mutation (SNP) | VAF 75/287 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1301439033, COSV66991215; called by muse, mutect2, varscan2
- LPIN3 | c.1259G>A p.R420K | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0.01); catalogued as rs754400245, COSV64717799; called by muse, mutect2, varscan2
- LRRCC1 | c.2893G>C p.D965H | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as COSV64483010; called by muse, mutect2, varscan2
- MAP1A | c.5057G>C p.R1686T | Missense Mutation (SNP) | VAF 71/84 reads (85%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.985); catalogued as COSV55807358; called by muse, mutect2, varscan2
- MAP3K5 | c.702G>C p.L234F | Missense Mutation (SNP) | VAF 73/161 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.883); catalogued as COSV62888069; called by muse, mutect2, varscan2
- MAP3K8 | c.275C>G p.S92C | Missense Mutation (SNP) | VAF 48/166 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.819); catalogued as COSV53919163; called by muse, mutect2, varscan2
- MYH1 | c.3981A>G p.I1327M | Missense Mutation (SNP) | VAF 24/282 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV99875524; called by muse, mutect2
- NLRP3 | c.2961C>A p.F987L | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60221763; called by muse, mutect2, varscan2
- NPAS4 | c.2024C>A p.S675* | Nonsense Mutation (SNP) | VAF 21/57 reads (37%) | catalogued as COSV60649292, COSV60649567; called by muse, mutect2, varscan2
- OR4D6 | c.457G>T p.G153C | Missense Mutation (SNP) | VAF 172/382 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as rs1170962632, COSV55659334; called by muse, mutect2, varscan2
- OR4E2 | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 349/772 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs376724041; called by muse, mutect2, varscan2
- OR52A1 | c.139C>A p.L47I | Missense Mutation (SNP) | VAF 68/85 reads (80%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as COSV61091955; called by muse, mutect2, varscan2
- OR56A3 | c.600C>A p.H200Q | Missense Mutation (SNP) | VAF 14/321 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV100290155; called by muse, mutect2
- OSCP1 | c.1099G>C p.E367Q (on ENST00000356637 / NM_001330493.1; = p.E357Q on NM_145047.5) | Missense Mutation (SNP) | VAF 40/53 reads (75%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as COSV52485407; called by muse, mutect2, varscan2
- P3H2 | c.758G>T p.G253V | Missense Mutation (SNP) | VAF 84/272 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV60019735; called by muse, mutect2, varscan2
- PABPC1 | c.1635G>C p.L545F | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV59400016; called by muse, mutect2, varscan2
- PLCZ1 | c.1067C>G p.T356R | Missense Mutation (SNP) | VAF 61/154 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV56850620, COSV56856935; called by muse, mutect2, varscan2
- PPP1R3A | c.1440A>T p.K480N | Missense Mutation (SNP) | VAF 127/305 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV52879090; called by muse, mutect2, varscan2
- PPP1R3A | c.1136C>T p.S379L | Missense Mutation (SNP) | VAF 208/514 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as rs1275417952, COSV52879106, COSV52880839; called by muse, mutect2, varscan2
- PTPRZ1 | c.4877G>T p.G1626V | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66433370; called by muse, mutect2, varscan2
- PYGO2 | c.1093G>A p.A365T | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs977306770, COSV63757306; called by muse, mutect2
- QPCTL | c.343G>C p.V115L | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.399); catalogued as COSV50003589; called by muse, mutect2, varscan2
- RABGGTA | c.1309A>C p.K437Q | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as COSV52862395; called by muse, mutect2, varscan2
- RFC1 | c.2171G>T p.G724V (on ENST00000381897 / NM_001363496.2; = p.G723V on NM_002913.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 83/201 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62898996, COSV62900641; called by muse, mutect2, varscan2
- RGPD2 | c.2644C>G p.L882V | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1331105324, COSV59530118; called by mutect2, varscan2
- RNF185 | c.223G>T p.V75L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.935); catalogued as COSV99839703; called by muse, mutect2
- SCRN1 | c.58G>A p.G20S | Missense Mutation (SNP) | VAF 73/174 reads (42%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.474); catalogued as COSV54129559; called by muse, mutect2, varscan2
- SCYL3 | c.539C>A p.T180N | Missense Mutation (SNP) | VAF 5/118 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.485); catalogued as COSV100884279; called by muse, mutect2
- SLC22A6 | c.1169A>T p.N390I | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.03); catalogued as COSV64559984; called by muse, mutect2, varscan2
- SLC6A5 | c.1514T>G p.V505G | Missense Mutation (SNP) | VAF 19/162 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100116377, COSV100116725; called by muse, mutect2
- SNRPA | c.60G>C p.K20N | Missense Mutation (SNP) | VAF 9/192 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99698921; called by muse, mutect2
- SP1 | c.314A>G p.N105S (on ENST00000327443 / NM_138473.3; = p.N98S on NM_003109.1) | Missense Mutation (SNP) | VAF 12/12 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs775622089, COSV59402240; called by muse, mutect2, varscan2
- STXBP5 | c.2146G>C p.G716R (on ENST00000321680 / NM_001127715.2; = p.A716P on NM_139244.4) | Missense Mutation (SNP) | VAF 44/164 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as COSV51649661; called by muse, mutect2, varscan2
- STYXL2 | c.1003G>T p.A335S | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as rs1306198701, COSV54803603; called by muse, mutect2, varscan2
- SYNE1 | c.10146-1G>C p.X3382_splice (on ENST00000367255 / NM_182961.4; = p.X3389_splice on NM_033071.3) | Splice Site (SNP) | VAF 65/189 reads (34%) | catalogued as COSV55040923, COSV99559720; called by muse, mutect2
- TET3 | c.2145G>C p.E715D | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV59880510; called by muse, varscan2
- TLN1 | c.7292del p.V2431Efs*23 | Frame Shift Del (DEL) | VAF 4/16 reads (25%) | catalogued as COSV59205852; called by mutect2, varscan2
- TNFRSF19 | c.1196A>T p.D399V | Missense Mutation (SNP) | VAF 93/168 reads (55%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.021); catalogued as COSV50312085; called by muse, mutect2, varscan2
- TRERF1 | c.1660C>A p.P554T | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.143); catalogued as COSV61668953; called by muse, mutect2, varscan2
- TRIM23 | c.232G>C p.V78L | Missense Mutation (SNP) | VAF 53/60 reads (88%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV51550212; called by muse, mutect2, varscan2
- TROAP | c.257G>T p.S86I | Missense Mutation (SNP) | VAF 90/113 reads (80%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as COSV57743499; called by muse, mutect2, varscan2
- TRUB1 | c.395T>A p.I132N | Missense Mutation (SNP) | VAF 355/561 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV53928816; called by muse, mutect2, varscan2
- TSHZ2 | c.2577G>T p.Q859H | Missense Mutation (SNP) | VAF 115/146 reads (79%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV61587701; called by muse, mutect2, varscan2
- UBE2J1 | c.429-1G>C p.X143_splice | Splice Site (SNP) | VAF 34/153 reads (22%) | catalogued as COSV70561024, COSV70561783; called by muse, mutect2, varscan2
- UHRF1BP1L | c.116T>C p.L39S | Missense Mutation (SNP) | VAF 19/244 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99691401; called by muse, mutect2
- UNC5D | c.1959A>T p.E653D | Missense Mutation (SNP) | VAF 100/238 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV54779575; called by muse, mutect2, varscan2
- WBP1L | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 70/260 reads (27%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.989); catalogued as COSV64009493; called by muse, mutect2, varscan2
- XIRP1 | c.2455A>C p.K819Q | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61137567; called by muse, mutect2, varscan2
- ABCC9 | c.3602_3611del p.L1201Qfs*33 | Frame Shift Del (DEL) | VAF 90/269 reads (33%) | called by mutect2, pindel, varscan2
- ANO5 | c.2080_2081del p.P694Sfs*7 | Frame Shift Del (DEL) | VAF 36/352 reads (10%) | called by mutect2, pindel, varscan2
- FAM111A | c.715_717del p.D239del | In Frame Del (DEL) | VAF 107/244 reads (44%) | called by pindel, varscan2
- FBF1 | c.673A>C p.K225Q (on ENST00000586717; = p.K239Q on NM_001319193.1) | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.046); called by muse, mutect2
- FXYD5 | c.364del p.Q122Rfs*65 | Frame Shift Del (DEL) | VAF 32/82 reads (39%) | called by mutect2, pindel, varscan2
- HTR1E | c.579_606del p.P194Tfs*20 | Frame Shift Del (DEL) | VAF 56/286 reads (20%) | called by mutect2, pindel
- KNG1 | c.1892_1896del p.M631Rfs*9 | Frame Shift Del (DEL) | VAF 130/446 reads (29%) | called by mutect2, pindel, varscan2
- MLH3 | c.1728_1763del p.A577_S588del | In Frame Del (DEL) | VAF 60/176 reads (34%) | called by mutect2, pindel
- OGT | c.2235_2243del p.D746_L748del | In Frame Del (DEL) | VAF 144/422 reads (34%) | called by mutect2, pindel, varscan2
- PSD | c.2323_2326+23del p.X775_splice | Splice Site (DEL) | VAF 12/33 reads (36%) | called by mutect2, pindel, varscan2
- TP53 | c.511_514del p.E171Lfs*2 | Frame Shift Del (DEL) | VAF 74/86 reads (86%) | called by mutect2, pindel, varscan2
- ZNF189 | c.1046_1056del p.C349Ffs*9 | Frame Shift Del (DEL) | VAF 86/227 reads (38%) | called by mutect2, pindel, varscan2
- ADGRL4 | c.1614T>C p.Y538= | Silent (SNP) | VAF 162/206 reads (79%) | catalogued as rs1417092233, COSV66060724; called by muse, mutect2, varscan2
- ATRNL1 | c.3486C>T p.V1162= | Silent (SNP) | VAF 6/88 reads (7%) | catalogued as rs782815173, COSV100370132; called by muse, mutect2
- BCL6 | c.1278G>A p.Q426= | Silent (SNP) | VAF 4/90 reads (4%) | called by muse, mutect2
- COL14A1 | c.120A>G p.V40= | Silent (SNP) | VAF 57/187 reads (30%) | catalogued as COSV52850320; called by muse, mutect2, varscan2
- CYP3A4 | c.1464C>A p.I488= (on ENST00000336411; = p.I457= on NM_017460.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 221/484 reads (46%) | catalogued as COSV60501411; called by muse, mutect2, varscan2
- FBH1 | c.996C>A p.L332= (on ENST00000362091 / NM_178150.3; = p.L383= on NM_032807.4) | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as COSV62982057; called by muse, mutect2, varscan2
- HPSE2 | c.546T>C p.A182= | Silent (SNP) | VAF 96/341 reads (28%) | catalogued as COSV65184304; called by muse, mutect2, varscan2
- IGSF9 | c.618C>T p.C206= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV100829615; called by muse, mutect2
- KDM2B | c.3387C>A p.L1129= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV65639099; called by muse, mutect2
- MCM4 | c.1656G>A p.E552= | Silent (SNP) | VAF 46/94 reads (49%) | catalogued as COSV50622023; called by muse, mutect2, varscan2
- MYO10 | c.5409G>A p.E1803= | Silent (SNP) | VAF 20/154 reads (13%) | catalogued as rs373885927; called by muse, mutect2, varscan2
- NR2E3 | c.1023C>T p.H341= | Silent (SNP) | VAF 6/9 reads (67%) | catalogued as rs200402349, COSV58907744; called by muse, mutect2
- OAS2 | c.1044G>C p.L348= | Silent (SNP) | VAF 406/466 reads (87%) | catalogued as COSV60801704; called by muse, mutect2, varscan2
- PDE3A | c.3129G>A p.E1043= | Silent (SNP) | VAF 131/321 reads (41%) | catalogued as rs1565464632, COSV62970171; called by muse, mutect2, varscan2
- SOX10 | c.1239C>T p.G413= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs1462524528, COSV62806349; called by muse, mutect2, varscan2
- SSTR3 | c.213G>T p.R71= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as COSV60728938; called by muse, mutect2, varscan2
- TAF3 | c.2631G>A p.G877= | Silent (SNP) | VAF 24/204 reads (12%) | catalogued as rs759030330, COSV60204561; called by muse, mutect2, varscan2
- TMEM132B | c.234C>G p.A78= | Silent (SNP) | VAF 136/348 reads (39%) | catalogued as COSV54748727; called by muse, mutect2, varscan2
- TRHDE | c.2412T>C p.V804= | Silent (SNP) | VAF 80/196 reads (41%) | catalogued as COSV53832743, COSV53838020; called by muse, mutect2, varscan2
- TRIM60 | c.255G>A p.R85= | Silent (SNP) | VAF 74/100 reads (74%) | catalogued as COSV61970107; called by muse, mutect2, varscan2
- TUT7 | c.3231C>G p.V1077= | Silent (SNP) | VAF 19/136 reads (14%) | catalogued as COSV52894635; called by muse, mutect2, varscan2
- TXN2 | c.312G>C p.V104= | Silent (SNP) | VAF 91/206 reads (44%) | catalogued as COSV53397241; called by muse, mutect2, varscan2
- USP36 | c.3042T>A p.P1014= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as COSV61750912; called by muse, mutect2, varscan2
- VCPIP1 | c.2829A>G p.P943= | Silent (SNP) | VAF 71/194 reads (37%) | catalogued as COSV60046458; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65502136 del TCTGTTTTCCTTCAAAGTATAGAGCT | 5'Flank (DEL) | VAF 34/117 reads (29%) | called by mutect2, pindel, varscan2
